Gene-level copy-number profile of specimen HCM-CSHL-0080-C25-85A from HCMI case HCM-CSHL-0080-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.9 years (22,238 days).
Specimen HCM-CSHL-0080-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 07d1eecb-94b2-4dd4-8a0b-9d870c1f32ca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0080-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/5598b932-ecd5-4145-9f8f-a3071ccac86f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,357; copy number 2: 23,459; copy number 3: 22,153; copy number 4: 9,123; copy number 5: 120; copy number 6: 116; copy number 7: 577; copy number 8: 334; copy number 9: 100; copy number 10: 10; copy number 11: 22; copy number 12: 5; copy number 33: 5; copy number 46: 2; copy number 48: 1; copy number 55: 10; copy number 62: 1; copy number 67: 2; copy number 73: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,044 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,121,786–90,173,414, 4 genes, copy number 7–8: IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr8:127,072,694–128,564,679, 23 genes, copy number 7–73: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr15:19,878,555–25,581,122, 283 genes, copy number 7 (broad region; genes not listed).
- chr15:29,120,254–38,062,340, 204 genes, copy number 7–8 (broad region; genes not listed).
- chr15:38,628,005–39,180,499, 1 gene, copy number 11 (within-gene range 3–11): LINC02694.
- chr15:38,851,306–39,497,074, 7 genes, copy number 7–11: AC022929.2, AC013652.1, AC087878.1, AC113146.1, C15orf54, AC013652.2, AC109630.1.
- chr15:79,559,256–83,108,754, 111 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr15:83,447,228–87,029,052, 86 genes, copy number 8–12 (within-gene range 6–12) (broad region; genes not listed).
- chr15:88,877,294–90,963,125, 98 genes, copy number 7–11 (broad region; genes not listed).
- chr15:91,408,708–101,979,093, 220 genes, copy number 7–9 (broad region; genes not listed).
- chr22:18,361,820–18,404,206, 3 genes, copy number 10: FAM230J, AC011718.1, PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene, copy number 10 (within-gene range 4–10): AC023490.2.
- chr22:29,432,944–29,478,868, 3 genes, copy number 7: RFPL4AP6, RFPL1S, RFPL1.

Autosomal genes at a single copy (total copy number 1): 1,619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
